CPTAC case C3L-02888 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b75b5b06-a90a-460d-924e-245ec4414aa1

Demographics
Sex at birth: female; Race: white; Year of birth: 1954; Vital status: Dead; Days to death: 1,213 days (3.3 years); Year of death: 2021; Cause of death: Cancer Related; Country of birth: Canada.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 62.8 years (22,949 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Residual disease: R1; Last known disease status: With tumor; Days to last known disease status: 1,213 days (3.3 years); Progression or recurrence: yes; Days to recurrence: 349 days; Days to last follow up: 1,183 days (3.2 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 1.7 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 20; Lymphatic invasion present: No; Margin status: Involved; Perineural invasion present: Yes; Vascular invasion present: No.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 413 days (1.1 years); Disease response: Stable Disease; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 741 days (2.0 years); Disease response: Progressive Disease; Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 1,183 days (3.2 years); Disease response: Progressive Disease; Karnofsky performance status: 40; ECOG performance status: 3.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 17.2; Cigarettes per day: 7; Tobacco smoking onset year: 1967; Alcohol history: Yes; Alcohol intensity: Non-Drinker; Exposure duration years: 55.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02888-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -9 days; Initial weight: 90 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02888-22: Section location: Head; Percent tumor nuclei: 30; Percent necrosis: 0.
- Sample C3L-02888-04: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -9 days; Initial weight: 126 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02888-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
